Somatic mutation profile of tumor specimen 0DG9FX from CCDI case PBBSVM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pleomorphic xanthoastrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.4 years (4,912 days).
Specimen 0DG9FX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80b26494-fdc3-4ce0-a1e7-e2624229a2ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DG9FT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d948af7c-16e7-49ed-b952-801a13225b8b

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, 5'UTR 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 303/892 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CEP290 | c.6031C>G p.R2011G | Missense Mutation (SNP) | VAF 155/802 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM072946; called by muse, mutect2, varscan2
- SLC29A4 | c.10G>A p.V4M | Missense Mutation (SNP) | VAF 154/714 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.038); catalogued as rs770079019; called by muse, mutect2, varscan2
- TRAF2 | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 160/496 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1564424508; called by muse, varscan2
- ZNF525 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 106/1208 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.422); called by muse, mutect2
- HTR1A | c.510G>A p.P170= | Silent (SNP) | VAF 21/563 reads (4%) | catalogued as COSV60499712; called by muse, mutect2
- PDZK1 | c.246G>C p.V82= | Silent (SNP) | VAF 65/647 reads (10%) | called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 28/990 reads (3%) | called by muse, mutect2
- C7orf61 | c.-27_-24del | 5'UTR (DEL) | VAF 34/186 reads (18%) | called by mutect2, varscan2
- H1-4 | c.-36C>T | 5'UTR (SNP) | VAF 92/412 reads (22%) | catalogued as rs751070469, COSV56801438; called by mutect2, varscan2
